Somatic mutation profile of tumor specimen 0DX5CA from CCDI case PBCPYW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 5.8 years (2,121 days).
Specimen 0DX5CA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 04271962-8aca-41f8-b292-57499826d52b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DX5C8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1540e64c-b31b-4396-9500-cad1840423bc

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ZBTB39 | c.1010A>G p.N337S | Missense Mutation (SNP) | VAF 189/471 reads (40%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs371008394; called by muse, mutect2, varscan2
- CXCL14 | c.315G>C p.K105N (on ENST00000337225; = p.K93N on NM_004887.5) | Missense Mutation (SNP) | VAF 108/392 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MYT1 | c.1846+1G>T p.X616_splice | Splice Site (SNP) | VAF 204/524 reads (39%) | called by muse, mutect2, varscan2
